Somatic mutation profile of tumor specimen BA3290D (aliquot aq-BA3290D) from BEATAML1.0 case 2753, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,448 days).
Specimen BA3290D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca4e6085-2375-47a1-b1ef-e009ff29965c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3392D (Solid Tissue Normal), aliquot aq-BA3392D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2890b29-fb7c-4a20-8f47-c8667497a0e0

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNU1 | c.2363C>G p.A788G | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV67757463; called by muse, mutect2, varscan2
- NOS1 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs913433943, COSV57609864; called by muse, mutect2
- STAB2 | c.6005C>G p.P2002R | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV66348032; called by muse, mutect2, varscan2
- ABCA4 | c.5478C>G p.N1826K | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2
- COL20A1 | c.1550G>C p.G517A | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.065); called by muse, mutect2, varscan2
